TCGA case TCGA-29-2427 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6f25001a-f890-4fd0-a994-e62a9ea5c6f3

Demographics
Sex at birth: female; Race: white; Age at index: 60 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.1 years (21,940 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Residual disease: R1; Days to last follow up: 1,900 days (5.2 years).
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 49 days; Number of cycles: 3; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 49 days; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 73 days; Days to treatment end: 157 days; Number of cycles: 6; Treatment dose: 660 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Recurrent Disease; Days to treatment start: 73 days; Days to treatment end: 157 days; Number of cycles: 6; Treatment dose: 5,640 mg; Prescribed dose: 940; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,584 days (4.3 years); Days to treatment end: 1,690 days (4.6 years); Number of cycles: 6; Treatment dose: 6 AUC; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,816 days (5.0 years); Days to treatment end: 1,900 days (5.2 years); Number of cycles: 5; Treatment dose: 510 mg; Route of administration: Intraperitoneal / Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 64.4 years (23,522 days); Days to diagnosis: 1,582 days (4.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,582 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,582 days (4.3 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,900 days (5.2 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-2427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-29-2427-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-29-2427-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-29-2427-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2, Route of administrations: Route of administration: IP; Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Abraxane.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,900 days; disease-specific survival: no event (censored), 1,900 days; disease-free interval: event (new tumor event after initially disease-free), 1,582 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,582 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-2427-01A-01D-0704-01): tumor purity 0.69, ploidy 1.8, whole-genome doublings 0.
